CCDI case PBBVWF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/465606e8-e6a5-4c95-8812-c9c575363ccc

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Neuroendocrine carcinoma, NOS: ICD-O-3 morphology code: 8246/3; Tissue or organ of origin: Appendix; Age at diagnosis: 16.8 years (6,144 days).

Biospecimens (3 samples)
- Sample 0DIOK0: Tissue type: Normal; Specimen type: Peripheral Whole Blood. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0DIOK9: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIOKH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
